Somatic mutation profile of tumor specimen ALCH-B26N-TTP1-A (aliquot ALCH-B26N-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B26N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 66.7 years (24,366 days).
Specimen ALCH-B26N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 247d9ded-503c-4de7-a829-7b20820f5c3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B26N-NB1-A (Blood Derived Normal), aliquot ALCH-B26N-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7992ddd-50f2-43b7-aa92-17d6a084949d

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, 5'UTR 2, Intron 2, Silent 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 22/353 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 31/299 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- C12orf29 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1372893314, COSV58351578; called by muse, mutect2
- CNTN3 | c.1576G>T p.D526Y | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55171706; called by muse, mutect2
- IFNGR2 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 10/295 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM131737, COSV99274494; called by muse, mutect2
- IGHA2 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs574773617; called by muse, mutect2
- KIF5C | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs532360681, COSV68482432; called by muse, mutect2
- RBM10 | c.1473_1474del p.S492Dfs*25 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | catalogued as rs1556779417; called by pindel, varscan2
- STAT3 | c.1847A>G p.E616G | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV52883602; called by muse, mutect2
- VGLL1 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs138345606, COSV65703134; called by muse, mutect2, varscan2
- ARID2 | c.935G>T p.C312F | Missense Mutation (SNP) | VAF 15/389 reads (4%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); called by muse, mutect2
- CASC3 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); called by muse, mutect2
- KIF17 | c.1280A>T p.E427V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- PTPRM | c.4250T>G p.V1417G | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SMG6 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- UNC13D | c.2597C>T p.P866L | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- NT5DC2 | c.1461A>C p.P487= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- SLC29A4 | c.306C>T p.T102= | Silent (SNP) | VAF 4/65 reads (6%) | catalogued as rs1208915896; called by muse, mutect2
- BRD7 | c.49+48C>T | Intron (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- CYP2A7P1 | n.552G>C | RNA (SNP) | VAF 15/241 reads (6%) | called by muse, mutect2
- ELOA | c.-9C>T | 5'UTR (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- EPHX1 | c.364+14A>T | Intron (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- PPP1R15A | c.-199A>G | 5'UTR (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
